Somatic mutation profile of tumor specimen TCGA-VD-AA8P-01A (aliquot TCGA-VD-AA8P-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8P, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.5 years (23,555 days).
Specimen TCGA-VD-AA8P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa726b80-52d2-4022-8952-3995ee6763ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8P-10A (Blood Derived Normal), aliquot TCGA-VD-AA8P-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d209f69-4203-48b1-86cc-571576634dfb

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, RNA 2, Splice Site 2, Silent 1, Translation Start Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALG1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs1332958042; called by muse, mutect2, varscan2
- FAM13B | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440211074, COSV50372349; called by muse, mutect2, varscan2
- ZNF446 | c.628-1G>C p.X210_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | catalogued as COSV59991238; called by muse, mutect2
- CDH4 | c.1137_1150del p.I380Cfs*3 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- CEMIP2 | c.2857A>G p.I953V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTDSP1 | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DNAH17 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.065); called by muse, mutect2
- INKA1 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB33A | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC13A5 | c.1437+2T>A p.X479_splice | Splice Site (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- TMEM35A | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- TWF2 | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYBU | c.783C>A p.P261= (on ENST00000276646 / NM_001099754.2; = p.P260= on NM_017786.6) | Silent (SNP) | VAF 104/168 reads (62%) | called by muse, mutect2, varscan2
- C8orf31 | n.463G>A | RNA (SNP) | VAF 23/40 reads (58%) | catalogued as rs1223664491; called by muse, mutect2, varscan2
- OSGIN1 | n.1696A>G | RNA (SNP) | VAF 19/35 reads (54%) | catalogued as rs1015014267; called by muse, mutect2, varscan2
